CCDI case PBCNTK — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/c1df2cb9-b804-432b-bf3c-4c24fc17e31c

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Craniopharyngioma, adamantinomatous: ICD-O-3 morphology code: 9351/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 8.8 years (3,209 days).

Biospecimens (3 samples)
- Sample 0DW41S: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DW424: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DW426: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
